Somatic mutation profile of tumor specimen 0DH734 from CCDI case PBBUGC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Age at diagnosis: 15.6 years (5,704 days).
Specimen 0DH734: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94368c7f-9e88-4aaf-ac89-dfb6a57ce898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH6ZX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88bb9df9-370c-49e1-b363-35c557b2405d

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HBE1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 716/1218 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1301082909, COSV53080244, COSV53080844; called by muse, mutect2, varscan2
- MDGA2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 318/1480 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs762291569; called by muse, mutect2, varscan2
- OR4E2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 377/819 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363447063, COSV57731627; called by muse, varscan2
- SOBP | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 290/676 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100432925, COSV57996489; called by muse, mutect2, varscan2
- MAMLD1 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 326/767 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TONSL | c.3154C>G p.L1052V | Missense Mutation (SNP) | VAF 268/593 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- XPO4 | c.2572G>A p.V858I | Missense Mutation (SNP) | VAF 402/944 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- COL17A1 | c.867C>A p.P289= | Silent (SNP) | VAF 200/908 reads (22%) | called by muse, mutect2, varscan2
- EGR1 | c.855G>A p.S285= | Silent (SNP) | VAF 233/472 reads (49%) | catalogued as rs752798429; called by muse, mutect2, varscan2
- GTF2E1 | c.249C>T p.D83= | Silent (SNP) | VAF 505/1177 reads (43%) | catalogued as rs200777200; called by muse, mutect2, varscan2
- ZNF845 | c.1083C>T p.D361= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1180196074; called by muse, varscan2
- KASH5 | c.798+88C>A | Intron (SNP) | VAF 59/131 reads (45%) | called by muse, mutect2, varscan2
- PREPL | c.-38C>A | 5'UTR (SNP) | VAF 271/692 reads (39%) | called by muse, mutect2, varscan2
